Somatic mutation profile of tumor specimen MP2PRT-PATJED-TBP1-A (aliquot MP2PRT-PATJED-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJED, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,130 days).
Specimen MP2PRT-PATJED-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f38f12a-55b0-4981-bbfd-137297dfa215.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJED-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJED-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89d675dd-fa8e-4807-8f33-8df31b130478

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/512 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CHGB | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 45/514 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs1313478981, COSV100973141, COSV66760190; called by muse, mutect2
- CNOT10 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as rs1330086295; called by muse, mutect2, varscan2
- EHMT2 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 31/960 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.835); catalogued as rs1421727953; called by muse, mutect2
- IQCA1L | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.617); catalogued as rs1007266901; called by muse, mutect2, varscan2
- MUC5B | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1427095732, COSV71594336; called by muse, mutect2
- PTCHD4 | c.2378G>C p.G793A | Missense Mutation (SNP) | VAF 53/530 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV59796393; called by muse, mutect2, varscan2
- STARD13 | c.2417C>T p.T806M (on ENST00000336934 / NM_001243476.3; = p.T688M on NM_052851.3) | Missense Mutation (SNP) | VAF 144/426 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391217095, COSV55234087; called by muse, varscan2
- AKAP13 | c.5618G>A p.R1873H (on ENST00000394518 / NM_007200.5; = p.R1877H on NM_006738.6) | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- ANK3 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.987); called by muse, varscan2
- C11orf95 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 27/403 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2
- CLDN24 | c.137G>C p.W46S | Missense Mutation (SNP) | VAF 25/515 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- COL4A5 | c.3766C>T p.P1256S | Missense Mutation (SNP) | VAF 17/645 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.11); called by muse, mutect2
- CPE | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATCAY | c.450C>T p.N150= | Silent (SNP) | VAF 110/586 reads (19%) | catalogued as rs777047303, COSV56654402; called by muse, varscan2
- CSNKA2IP | c.1776T>A p.A592= | Silent (SNP) | VAF 111/392 reads (28%) | called by muse, mutect2, varscan2
- HTR1E | c.417C>T p.A139= | Silent (SNP) | VAF 36/682 reads (5%) | catalogued as rs146428063, COSV100541098; called by muse, mutect2
- OPN1LW | c.981G>T p.R327= | Silent (SNP) | VAF 37/494 reads (7%) | called by muse, mutect2
